Somatic mutation profile of cancer-model specimen HCM-WCMC-1284-C67-85A (3D Organoid; aliquot HCM-WCMC-1284-C67-85A-01D-A905-36), derived from the primary tumor of HCMI case HCM-WCMC-1284-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-WCMC-1284-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 821ab8dc-2fc7-4f03-862c-670f2865e5a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1284-C67-11A (Slides), aliquot HCM-WCMC-1284-C67-11A-15D-A905-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9827e9c-a697-4b4f-9198-f6b5e76cda15

The open-access MAF lists 172 somatic variants for this specimen: 130 protein-altering or splice-affecting, 38 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 38, Nonsense Mutation 17, Intron 2, Splice Site 1, 3'UTR 1, In Frame Del 1, Splice Region 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHEK2 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 350/700 reads (50%) | catalogued as rs587781269, CM110734, COSV60421481; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.4496T>C p.L1499P | Missense Mutation (SNP) | VAF 409/903 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52115693, COSV52125172, COSV52125754; called by muse, mutect2, varscan2
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 327/743 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 280/613 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AIMP2 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 351/722 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV56151895, COSV56151903; called by muse, mutect2, varscan2
- ANKRD30A | c.1731G>C p.Q577H (on ENST00000611781; = p.Q521H on NM_052997.2) | Missense Mutation (SNP) | VAF 101/680 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV64623783; called by muse, varscan2
- ARID1B | c.4651G>T p.E1551* | Nonsense Mutation (SNP) | VAF 496/924 reads (54%) | catalogued as rs1554235925, COSV51678781; called by muse, mutect2, varscan2
- C17orf97 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 226/475 reads (48%) | catalogued as rs1304810206; called by muse, mutect2, varscan2
- C19orf57 | c.1053G>C p.E351D | Missense Mutation (SNP) | VAF 510/1025 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as rs983428153; called by muse, mutect2, varscan2
- C7orf61 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 504/978 reads (52%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1417789451; called by muse, mutect2, varscan2
- CFAP20 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 428/922 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.094); catalogued as rs764778355; called by muse, mutect2, varscan2
- CUBN | c.2927C>T p.T976I | Missense Mutation (SNP) | VAF 26/794 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV64708623; called by muse, mutect2
- DEFB112 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 294/659 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0.017); catalogued as rs146242544; called by muse, mutect2, varscan2
- EFCAB12 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 473/968 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as COSV100394474; called by muse, mutect2, varscan2
- EFCAB6 | c.4438G>T p.E1480* | Nonsense Mutation (SNP) | VAF 238/485 reads (49%) | catalogued as COSV53063018; called by muse, mutect2, varscan2
- EIF4A1 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 368/768 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs199974690, COSV53441875; called by muse, mutect2, varscan2
- EP300 | c.1604C>A p.S535* | Nonsense Mutation (SNP) | VAF 242/485 reads (50%) | catalogued as COSV54341353; called by muse, mutect2, varscan2
- ETV4 | c.8G>C p.R3P | Missense Mutation (SNP) | VAF 349/730 reads (48%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.989); catalogued as rs1426178575; called by muse, mutect2, varscan2
- FAM153A | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 330/701 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as COSV62363563; called by muse, mutect2, varscan2
- FGD5 | c.2284C>T p.R762W | Missense Mutation (SNP) | VAF 387/828 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768184216; called by muse, mutect2, varscan2
- FHOD3 | c.4184C>G p.S1395C (on ENST00000359247 / NM_001281739.3; = p.S1412C on NM_025135.5) | Missense Mutation (SNP) | VAF 258/585 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57185201; called by muse, mutect2, varscan2
- GCOM1 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 238/456 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.32); catalogued as COSV51093995, COSV51096943; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 534/1198 reads (45%) | SIFT tolerated (0.07); catalogued as rs760519128; called by muse, varscan2
- GRIP1 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 302/670 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54030917; called by muse, mutect2, varscan2
- HELZ2 | c.7606C>T p.R2536W (on ENST00000467148 / NM_001037335.2; = p.R1967W on NM_033405.3) | Missense Mutation (SNP) | VAF 460/900 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs369824932; called by muse, mutect2, varscan2
- HERC2 | c.4823C>T p.P1608L | Missense Mutation (SNP) | VAF 152/462 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as rs781394266; called by muse, mutect2, varscan2
- ITPR1 | c.5287G>A p.G1763S (on ENST00000354582; = p.G1708S on NM_002222.7) | Missense Mutation (SNP) | VAF 366/793 reads (46%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.874); catalogued as COSV100231673; called by muse, mutect2, varscan2
- KIF2C | c.760-1G>A p.X254_splice | Splice Site (SNP) | VAF 259/617 reads (42%) | catalogued as COSV100945886; called by muse, mutect2, varscan2
- KMT2C | c.13750C>T p.R4584W | Missense Mutation (SNP) | VAF 487/932 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747850540, COSV51428250; called by muse, mutect2, varscan2
- L1TD1 | c.1439A>T p.E480V | Missense Mutation (SNP) | VAF 367/690 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs373045440; called by muse, mutect2, varscan2
- MAPK15 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 458/891 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs782408799; called by muse, varscan2
- MIER2 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 378/749 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53398974; called by muse, mutect2, varscan2
- MKI67 | c.6832G>C p.D2278H | Missense Mutation (SNP) | VAF 304/652 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); catalogued as COSV64075443; called by muse, varscan2
- NACC1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 489/991 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99456836; called by muse, mutect2, varscan2
- NAXE | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 252/564 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs369152490; called by muse, mutect2, varscan2
- NELL1 | c.2324G>C p.R775P | Missense Mutation (SNP) | VAF 286/625 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV100122487, COSV54263969, COSV54298710; called by muse, mutect2, varscan2
- ODF3B | c.525C>G p.F175L | Missense Mutation (SNP) | VAF 303/642 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1341372388; called by muse, mutect2, varscan2
- OR6K3 | c.183C>G p.I61M (on ENST00000368146; = p.I45M on NM_001005327.2) | Missense Mutation (SNP) | VAF 339/677 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV63746116; called by muse, mutect2, varscan2
- PICALM | c.1211C>G p.S404C | Missense Mutation (SNP) | VAF 27/789 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.625); catalogued as rs1424094395; called by muse, mutect2
- PKP4 | c.3524A>C p.K1175T | Missense Mutation (SNP) | VAF 258/560 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as COSV100734034; called by mutect2, varscan2
- PRPF38B | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 368/762 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64223491; called by muse, mutect2, varscan2
- PYCR3 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 49/866 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55306528; called by muse, mutect2
- RAB32 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 248/455 reads (55%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); catalogued as rs1159385512, COSV62249166; called by muse, mutect2, varscan2
- ROR2 | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 379/718 reads (53%) | catalogued as rs943841260; called by muse, mutect2, varscan2
- RPH3A | c.221A>G p.E74G (on ENST00000389385 / NM_001143854.2; = p.E70G on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 257/556 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs540323896; called by muse, mutect2, varscan2
- SCARA3 | c.1673C>G p.S558* | Nonsense Mutation (SNP) | VAF 588/1161 reads (51%) | catalogued as COSV57271786; called by muse, mutect2, varscan2
- SLC25A3 | c.130C>G p.R44G | Missense Mutation (SNP) | VAF 515/1052 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1044154623; called by muse, mutect2, varscan2
- SNRPB | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 86/1080 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.177); catalogued as rs748627420; called by muse, mutect2
- TTN | c.17659G>C p.E5887Q (on ENST00000591111; = p.E4960Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 294/598 reads (49%) | PolyPhen benign (0.019); catalogued as COSV104413470; called by muse, mutect2, varscan2
- UGT2B10 | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 290/567 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs773034258; called by muse, mutect2, varscan2
- UNC13C | c.4519G>A p.E1507K | Missense Mutation (SNP) | VAF 238/498 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as rs749619544, COSV99515933; called by muse, mutect2, varscan2
- USP9X | c.6416C>T p.S2139F | Missense Mutation (SNP) | VAF 219/224 reads (98%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV61072009; called by muse, mutect2, varscan2
- AC097637.1 | c.38G>C p.R13T | Missense Mutation (SNP) | VAF 352/767 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRV1 | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 169/383 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ALS2 | c.3652G>T p.D1218Y | Missense Mutation (SNP) | VAF 269/575 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKIB1 | c.1620C>T p.C540= | Splice Region (SNP) | VAF 176/425 reads (41%) | called by muse, mutect2, varscan2
- ANOS1 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 378/378 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- APBB3 | c.1201G>C p.E401Q (on ENST00000357560 / NM_133173.2; = p.E408Q on NM_006051.3) | Missense Mutation (SNP) | VAF 364/727 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF10 | c.2611C>G p.H871D (on ENST00000398564; = p.H846D on NM_014629.4) | Missense Mutation (SNP) | VAF 353/726 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BOD1L1 | c.1535G>C p.R512T | Missense Mutation (SNP) | VAF 271/542 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C12orf29 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 376/760 reads (49%) | called by muse, varscan2
- C8orf34 | c.1270A>C p.T424P | Missense Mutation (SNP) | VAF 187/597 reads (31%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CCDC102A | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 300/629 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CCDC88B | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 363/739 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCNT2 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 279/580 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNGB1 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 440/976 reads (45%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, varscan2
- CNOT3 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 437/898 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- COX16 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 271/605 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DAAM1 | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 372/723 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- DDX60L | c.2209C>T p.P737S | Missense Mutation (SNP) | VAF 311/677 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- DHFR | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 214/576 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- EPPK1 | c.4842C>G p.I1614M | Missense Mutation (SNP) | VAF 545/1107 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- EPS8 | c.52C>A p.Q18K | Missense Mutation (SNP) | VAF 172/417 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FAM186A | c.4483C>G p.L1495V | Missense Mutation (SNP) | VAF 472/1272 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.134); called by muse, varscan2
- FAM214A | c.865C>G p.P289A | Missense Mutation (SNP) | VAF 513/1005 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- FAM71E2 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 383/832 reads (46%) | called by muse, varscan2
- FANCB | c.2536C>T p.Q846* | Nonsense Mutation (SNP) | VAF 392/393 reads (100%) | called by muse, mutect2, varscan2
- FAT4 | c.11678G>T p.G3893V | Missense Mutation (SNP) | VAF 395/779 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRYL | c.8434G>A p.D2812N | Missense Mutation (SNP) | VAF 258/573 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- GARRE1 | c.1345C>G p.Q449E | Missense Mutation (SNP) | VAF 289/679 reads (43%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GIMAP5 | c.833T>G p.L278W | Missense Mutation (SNP) | VAF 32/1114 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GLIPR2 | c.118C>G p.Q40E | Missense Mutation (SNP) | VAF 196/419 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- GOLGA4 | c.3606G>C p.K1202N | Missense Mutation (SNP) | VAF 353/727 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- GOLGA4 | c.4440G>C p.Q1480H | Missense Mutation (SNP) | VAF 310/618 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- HEATR9 | c.977C>G p.S326* | Nonsense Mutation (SNP) | VAF 452/914 reads (49%) | called by muse, varscan2
- JAG2 | c.270C>A p.Y90* | Nonsense Mutation (SNP) | VAF 44/1177 reads (4%) | called by muse, mutect2
- JMJD1C | c.6783G>C p.L2261F | Missense Mutation (SNP) | VAF 272/583 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM7A | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 187/429 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KMT2D | c.15611_15623del p.A5204Gfs*35 | Frame Shift Del (DEL) | VAF 358/852 reads (42%) | called by mutect2, varscan2
- KMT2D | c.10495C>T p.Q3499* | Nonsense Mutation (SNP) | VAF 422/907 reads (47%) | called by muse, mutect2, varscan2
- MAP2K5 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 23/158 reads (15%) | called by muse, mutect2, varscan2
- MAP3K2 | c.1517A>G p.K506R | Missense Mutation (SNP) | VAF 461/919 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- MKI67 | c.6722G>C p.R2241T | Missense Mutation (SNP) | VAF 389/767 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, varscan2
- MUC16 | c.25715C>G p.S8572* | Nonsense Mutation (SNP) | VAF 398/828 reads (48%) | called by muse, mutect2, varscan2
- MVK | c.338T>G p.L113R | Missense Mutation (SNP) | VAF 376/767 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAPB | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 244/529 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- NPIPB15 | c.1243C>G p.Q415E | Missense Mutation (SNP) | VAF 318/1814 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); called by muse, varscan2
- NUP155 | c.2067G>C p.K689N (on ENST00000231498 / NM_153485.3; = p.K630N on NM_004298.4) | Missense Mutation (SNP) | VAF 248/531 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- OSBPL5 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 474/966 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- PALM | c.304G>C p.D102H | Missense Mutation (SNP) | VAF 529/1152 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); called by muse, mutect2
- PDCD2 | c.718A>G p.I240V | Missense Mutation (SNP) | VAF 232/514 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PHF21A | c.1485A>T p.R495S (on ENST00000418153 / NM_001101802.3; = p.R449S on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/855 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2
- PLXNA1 | c.5340C>A p.F1780L | Missense Mutation (SNP) | VAF 369/794 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POU1F1 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 349/720 reads (48%) | called by muse, mutect2, varscan2
- PPP5C | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 254/572 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.727); called by muse, varscan2
- RBM27 | c.2288C>T p.S763L | Missense Mutation (SNP) | VAF 353/787 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RBM42 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 623/1325 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- RIF1 | c.6340_6345del p.H2114_H2115del | In Frame Del (DEL) | VAF 212/522 reads (41%) | called by mutect2, varscan2
- RMDN1 | c.845G>C p.W282S | Missense Mutation (SNP) | VAF 375/801 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- RNFT1 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 315/639 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPE65 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 230/513 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMURF1 | c.1397C>G p.S466C | Missense Mutation (SNP) | VAF 261/574 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SNX9 | c.1407G>C p.K469N | Missense Mutation (SNP) | VAF 294/665 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SOX17 | c.1138C>G p.Q380E | Missense Mutation (SNP) | VAF 475/946 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- STOX1 | c.1999C>T p.Q667* | Nonsense Mutation (SNP) | VAF 488/894 reads (55%) | called by muse, mutect2, varscan2
- SYNE1 | c.871G>A p.D291N (on ENST00000367255 / NM_182961.4; = p.D298N on NM_033071.3) | Missense Mutation (SNP) | VAF 236/578 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TAF1A | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 246/510 reads (48%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TAF7 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 271/568 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- TGM5 | c.859A>T p.T287S (on ENST00000220420 / NM_201631.4; = p.T205S on NM_004245.4) | Missense Mutation (SNP) | VAF 339/714 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TNFSF13B | c.63A>C p.E21D | Missense Mutation (SNP) | VAF 385/789 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TOPAZ1 | c.3175G>C p.G1059R | Missense Mutation (SNP) | VAF 175/412 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRMT1L | c.1915C>A p.H639N | Missense Mutation (SNP) | VAF 201/480 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- USP9X | c.4645G>T p.G1549* | Nonsense Mutation (SNP) | VAF 19/387 reads (5%) | called by muse, mutect2
- WDR54 | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 423/799 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZAN | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 357/772 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFYVE9 | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 312/670 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- ZMYND19 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 374/736 reads (51%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF148 | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 420/935 reads (45%) | called by muse, mutect2, varscan2
- ZNF497 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 448/968 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- ZNF808 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 312/666 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ADGRA3 | c.459C>T p.T153= | Silent (SNP) | VAF 279/551 reads (51%) | catalogued as rs760105617; called by muse, mutect2, varscan2
- C1orf74 | c.589C>T p.L197= | Silent (SNP) | VAF 392/823 reads (48%) | called by muse, mutect2, varscan2
- CACNA1A | c.4422C>T p.D1474= | Silent (SNP) | VAF 300/598 reads (50%) | catalogued as rs374555263; ClinVar: likely benign; called by muse, varscan2
- CASKIN1 | c.2571G>A p.P857= | Silent (SNP) | VAF 648/1384 reads (47%) | catalogued as rs759731785, COSV58212568; called by muse, mutect2, varscan2
- CLSTN2 | c.252G>A p.K84= | Silent (SNP) | VAF 297/589 reads (50%) | catalogued as COSV101515613; called by muse, mutect2, varscan2
- CRACD | c.2310G>A p.G770= | Silent (SNP) | VAF 582/1102 reads (53%) | catalogued as rs746345219, COSV99948928; called by muse, mutect2, varscan2
- CUL1 | c.2121C>A p.R707= | Silent (SNP) | VAF 36/744 reads (5%) | called by muse, mutect2
- DGKD | c.1962G>A p.K654= (on ENST00000264057 / NM_152879.3; = p.K610= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 384/813 reads (47%) | called by muse, mutect2, varscan2
- DNAH5 | c.528C>G p.L176= | Silent (SNP) | VAF 408/836 reads (49%) | catalogued as COSV99454473; called by muse, mutect2, varscan2
- EBF2 | c.489C>T p.C163= | Silent (SNP) | VAF 306/667 reads (46%) | catalogued as COSV68780357; called by muse, mutect2, varscan2
- EFR3B | c.2388C>T p.Y796= | Silent (SNP) | VAF 440/915 reads (48%) | catalogued as rs1177829793; called by muse, mutect2, varscan2
- FAM71E2 | c.324C>T p.L108= | Silent (SNP) | VAF 304/666 reads (46%) | catalogued as rs961471384; called by muse, varscan2
- HDAC4 | c.477G>A p.E159= | Silent (SNP) | VAF 291/599 reads (49%) | called by muse, mutect2, varscan2
- HEATR9 | c.1059C>G p.L353= | Silent (SNP) | VAF 422/904 reads (47%) | called by muse, mutect2, varscan2
- IFFO2 | c.42C>T p.F14= | Silent (SNP) | VAF 393/868 reads (45%) | called by muse, mutect2, varscan2
- ITFG2 | c.633G>A p.L211= | Silent (SNP) | VAF 348/769 reads (45%) | catalogued as rs981684476; called by muse, mutect2, varscan2
- KCNH5 | c.2130C>T p.F710= | Silent (SNP) | VAF 453/920 reads (49%) | catalogued as rs1208483577; called by muse, mutect2, varscan2
- KCNV2 | c.990C>T p.F330= | Silent (SNP) | VAF 878/879 reads (100%) | catalogued as rs773388753, COSV66057256, COSV66058001; called by muse, mutect2, varscan2
- KRTAP19-7 | c.54C>T p.F18= | Silent (SNP) | VAF 375/789 reads (48%) | catalogued as rs572700402, COSV58366022, COSV58366262; called by muse, mutect2, varscan2
- LHPP | c.495G>A p.L165= | Silent (SNP) | VAF 430/921 reads (47%) | called by muse, mutect2
- MED12L | c.549G>A p.P183= | Silent (SNP) | VAF 260/529 reads (49%) | catalogued as rs148202747; called by muse, mutect2, varscan2
- MED13 | c.5169G>C p.R1723= | Silent (SNP) | VAF 383/807 reads (47%) | called by muse, mutect2, varscan2
- MEX3C | c.144G>A p.L48= | Silent (SNP) | VAF 354/712 reads (50%) | called by muse, mutect2, varscan2
- NEFL | c.1272C>T p.Y424= | Silent (SNP) | VAF 421/918 reads (46%) | catalogued as rs550984119, COSV99648009; called by muse, mutect2, varscan2
- POU1F1 | c.759G>T p.L253= | Silent (SNP) | VAF 348/717 reads (49%) | catalogued as COSV99773269; called by muse, mutect2, varscan2
- PRTN3 | c.390C>T p.L130= | Silent (SNP) | VAF 351/771 reads (46%) | called by muse, mutect2, varscan2
- RAB27A | c.267C>T p.F89= | Silent (SNP) | VAF 271/536 reads (51%) | called by muse, mutect2, varscan2
- RTTN | c.108C>T p.Y36= | Silent (SNP) | VAF 414/819 reads (51%) | catalogued as COSV55341424; called by muse, mutect2, varscan2
- SLC12A5 | c.15C>T p.F5= | Silent (SNP) | VAF 318/687 reads (46%) | called by muse, mutect2, varscan2
- SLC17A9 | c.165C>T p.F55= | Silent (SNP) | VAF 493/1001 reads (49%) | catalogued as rs1204167432, COSV64847072; called by muse, mutect2, varscan2
- SLC38A3 | c.1467C>T p.I489= | Silent (SNP) | VAF 294/595 reads (49%) | catalogued as rs1275943011; called by muse, varscan2
- TBC1D4 | c.1725C>T p.F575= | Silent (SNP) | VAF 174/387 reads (45%) | called by muse, mutect2, varscan2
- TEDC2 | c.21G>C p.S7= | Silent (SNP) | VAF 383/767 reads (50%) | called by muse, mutect2, varscan2
- TIGD3 | c.150G>A p.K50= | Silent (SNP) | VAF 521/1040 reads (50%) | catalogued as rs777691849; called by muse, mutect2, varscan2
- TPM2 | c.558C>T p.A186= | Silent (SNP) | VAF 335/661 reads (51%) | catalogued as rs746177794; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TRIM60 | c.1332C>T p.F444= | Silent (SNP) | VAF 256/608 reads (42%) | catalogued as COSV61971030; called by muse, mutect2, varscan2
- UNK | c.1296C>T p.F432= | Silent (SNP) | VAF 252/519 reads (49%) | catalogued as rs368755581; called by muse, mutect2, varscan2
- VEZF1 | c.813C>T p.A271= | Silent (SNP) | VAF 279/608 reads (46%) | called by muse, mutect2, varscan2
- CDH13 | c.157+34C>T | Intron (SNP) | VAF 306/704 reads (43%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-10632G>A | Intron (SNP) | VAF 438/843 reads (52%) | called by muse, mutect2, varscan2
- MYOG | c.*147C>A | 3'UTR (SNP) | VAF 378/805 reads (47%) | called by muse, mutect2, varscan2
- VPS11 | c.-960G>C | 5'UTR (SNP) | VAF 271/580 reads (47%) | called by muse, mutect2, varscan2
